Somatic mutation profile of tumor specimen ALCH-B53R-TTP1-A (aliquot ALCH-B53R-TTP1-A-1-0-D-A83F-36) from ALCHEMIST case ALCH-B53R, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 62.8 years (22,944 days).
Specimen ALCH-B53R-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ad353f02-442f-44ec-b16d-9a226d7e3fcb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B53R-NB1-A (Blood Derived Normal), aliquot ALCH-B53R-NB1-A-1-0-D-A83F-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/98a28c76-02a4-42bd-8e58-dbdbe02fb8a2

The open-access MAF lists 94 somatic variants for this specimen: 64 protein-altering or splice-affecting, 22 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 22, Nonsense Mutation 5, 3'UTR 3, 5'UTR 3, Splice Site 3, Intron 2, Splice Region 2, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CASR | c.679C>T p.R227* | Nonsense Mutation (SNP) | VAF 31/212 reads (15%) | catalogued as rs1085307984, CM107259, COSV56134117; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 328/727 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- ADAM33 | c.1132G>A p.G378R | Missense Mutation (SNP) | VAF 10/137 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs775132860; called by muse, mutect2
- ANXA6 | c.61G>A p.D21N | Missense Mutation (SNP) | VAF 30/325 reads (9%) | SIFT tolerated (0.64); PolyPhen benign (0.01); catalogued as COSV100636922; called by muse, mutect2
- ASXL3 | c.212A>G p.K71R | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.056); catalogued as rs941552523; called by muse, mutect2, varscan2
- ATRX | c.3835G>T p.E1279* | Nonsense Mutation (SNP) | VAF 42/219 reads (19%) | catalogued as COSV100970278; called by muse, mutect2, varscan2
- BROX | c.638C>T p.A213V | Missense Mutation (SNP) | VAF 32/260 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs372955065; called by muse, mutect2, varscan2
- CPA5 | c.376C>T p.R126W | Missense Mutation (SNP) | VAF 25/250 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); catalogued as rs782238336; called by muse, mutect2, varscan2
- DSTYK | c.780G>T p.R260S | Missense Mutation (SNP) | VAF 18/278 reads (6%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs753457437; called by muse, mutect2
- DYRK1B | c.179A>G p.N60S | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs768717702; called by mutect2, varscan2
- KRTAP4-2 | c.305G>A p.R102H | Missense Mutation (SNP) | VAF 62/396 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.515); catalogued as rs754307555, COSV66658212; called by muse, mutect2, varscan2
- MUC16 | c.38789G>A p.R12930H | Missense Mutation (SNP) | VAF 26/296 reads (9%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs778470162, COSV101202465, COSV67447347; called by muse, mutect2
- NCKAP1 | c.1330G>A p.E444K | Missense Mutation (SNP) | VAF 10/169 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.975); catalogued as COSV100720247; called by muse, mutect2
- OBSCN | c.5437C>T p.R1813W | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs578019993; called by muse, mutect2, varscan2
- PCDHA5 | c.1079A>G p.E360G | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs782102904, COSV65357582; called by muse, mutect2
- PGM5 | c.520C>T p.R174* | Nonsense Mutation (SNP) | VAF 19/121 reads (16%) | catalogued as rs1452229536; called by muse, mutect2, varscan2
- PMS2 | c.716T>G p.L239R | Missense Mutation (SNP) | VAF 18/191 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1060503136; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RASGRF2 | c.2585G>A p.R862Q | Missense Mutation (SNP) | VAF 11/136 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as rs1324998890; called by muse, mutect2
- RGS6 | c.562G>T p.E188* | Nonsense Mutation (SNP) | VAF 12/246 reads (5%) | catalogued as COSV59566694; called by muse, mutect2
- RNFT2 | c.1051C>T p.R351C | Missense Mutation (SNP) | VAF 18/194 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs140072696; called by muse, mutect2
- RYR2 | c.11507C>T p.T3836I | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs1421239060; called by muse, mutect2
- STRIP1 | c.890C>T p.T297M | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1186518003; called by muse, mutect2
- TPCN2 | c.2003+1G>A p.X668_splice | Splice Site (SNP) | VAF 16/226 reads (7%) | catalogued as rs145113932; called by muse, mutect2
- UTP4 | c.1939T>C p.Y647H | Missense Mutation (SNP) | VAF 20/398 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as rs377461398; called by muse, mutect2
- ZNF708 | c.788G>A p.R263Q | Missense Mutation (SNP) | VAF 25/488 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs878869481, COSV63608852; called by muse, mutect2
- ZNF784 | c.892G>C p.G298R | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as rs1305187572; called by muse, mutect2, varscan2
- ACSM2A | c.1698G>T p.K566N (on ENST00000219054; = p.K487N on NM_001308169.2) | Missense Mutation (SNP) | VAF 19/295 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.681); called by muse, mutect2
- AKAP8 | c.1034A>G p.K345R | Missense Mutation (SNP) | VAF 15/155 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKFN1 | c.3608G>A p.R1203Q (on ENST00000653862; = p.R1056Q on NM_001365758.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ATP2A3 | c.1381G>T p.A461S | Missense Mutation (SNP) | VAF 40/197 reads (20%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP2A3 | c.1380G>T p.Q460H | Missense Mutation (SNP) | VAF 40/200 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- B3GAT1 | c.283C>A p.R95S | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CACNA1A | c.2009G>T p.W670L | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- CCDC150 | c.1792A>G p.K598E | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- CCDC178 | c.811C>T p.P271S | Missense Mutation (SNP) | VAF 12/234 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.859); called by muse, mutect2
- CD300LB | c.42C>A p.G14= | Splice Region (SNP) | VAF 4/34 reads (12%) | called by muse, varscan2
- CENPJ | c.3495G>C p.K1165N | Missense Mutation (SNP) | VAF 26/382 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); called by muse, mutect2
- DUS4L-BCAP29 | c.721dup p.M241Nfs*39 | Frame Shift Ins (INS) | VAF 60/328 reads (18%) | called by mutect2, varscan2
- EGFR | c.2701G>T p.G901W | Missense Mutation (SNP) | VAF 29/521 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EGFR | c.2701+1G>T p.X901_splice | Splice Site (SNP) | VAF 30/518 reads (6%) | called by muse, mutect2
- EPHA6 | c.1903A>T p.M635L (on ENST00000389672 / NM_001080448.3; = p.M27L on NM_173655.4) | Missense Mutation (SNP) | VAF 16/212 reads (8%) | SIFT tolerated (0.83); PolyPhen benign (0.001); called by muse, mutect2
- GNPDA2 | c.512C>T p.A171V | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.893); called by muse, mutect2
- GREB1L | c.4375G>A p.D1459N | Missense Mutation (SNP) | VAF 9/117 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); called by muse, mutect2
- KAT7 | c.1373G>T p.G458V | Missense Mutation (SNP) | VAF 93/429 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAP3K2 | c.1700T>A p.M567K | Missense Mutation (SNP) | VAF 42/436 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- MYH2 | c.5102C>A p.T1701K | Missense Mutation (SNP) | VAF 15/523 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.17); called by muse, mutect2
- PLCB2 | c.2602+4T>A | Splice Region (SNP) | VAF 14/204 reads (7%) | called by muse, mutect2
- POLR2H | c.73+2T>C p.X25_splice | Splice Site (SNP) | VAF 12/111 reads (11%) | called by muse, mutect2, varscan2
- PPP2R5B | c.619C>G p.P207A | Missense Mutation (SNP) | VAF 10/191 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2
- RAB15 | c.250A>T p.I84L | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- RABGEF1 | c.854T>A p.I285N (on ENST00000439720 / NM_001287061.2; = p.I272N on NM_014504.3 and 29 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/246 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- RRM2B | c.408G>T p.E136D | Missense Mutation (SNP) | VAF 26/416 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- RTTN | c.1150G>A p.V384I | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.01); called by muse, mutect2
- SERPINB3 | c.964G>T p.G322C | Missense Mutation (SNP) | VAF 38/208 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SLK | c.2045A>T p.E682V | Missense Mutation (SNP) | VAF 6/107 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.399); called by muse, mutect2
- ST6GALNAC5 | c.413G>T p.R138L | Missense Mutation (SNP) | VAF 16/214 reads (7%) | PolyPhen possibly damaging (0.796); called by muse, mutect2
- TCF20 | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 11/161 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); called by muse, mutect2
- TEKT4 | c.438C>A p.C146* | Nonsense Mutation (SNP) | VAF 19/109 reads (17%) | called by muse, mutect2, varscan2
- TP53 | c.219_235del p.A74Sfs*69 | Frame Shift Del (DEL) | VAF 18/198 reads (9%) | called by mutect2, pindel
- TRPS1 | c.1035C>A p.N345K (on ENST00000220888 / NM_001330599.2; = p.N358K on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/328 reads (9%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); called by muse, mutect2
- UNC79 | c.787G>T p.A263S (on ENST00000393151 / NM_001346218.2; = p.A86S on NM_020818.5) | Missense Mutation (SNP) | VAF 7/115 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.041); called by muse, mutect2
- ZBTB38 | c.2398G>A p.G800R | Missense Mutation (SNP) | VAF 40/334 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZNF319 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZNF470 | c.967C>A p.Q323K | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- ADAMTSL2 | c.1581C>T p.S527= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as rs1306035494; called by muse, mutect2, varscan2
- ATP13A5 | c.1530G>A p.Q510= | Silent (SNP) | VAF 20/115 reads (17%) | called by muse, mutect2
- DCC | c.1782T>C p.Y594= | Silent (SNP) | VAF 16/364 reads (4%) | catalogued as COSV59139772; called by muse, mutect2
- DHTKD1 | c.1002T>G p.A334= | Silent (SNP) | VAF 8/56 reads (14%) | called by muse, mutect2, varscan2
- EPGN | c.360A>G p.L120= | Silent (SNP) | VAF 13/291 reads (4%) | called by muse, mutect2
- ESR1 | c.1134T>A p.L378= | Silent (SNP) | VAF 31/525 reads (6%) | called by muse, mutect2
- GPR153 | c.543C>T p.G181= | Silent (SNP) | VAF 20/292 reads (7%) | catalogued as rs777005637, COSV64938749; called by muse, mutect2
- HTR5A | c.522G>A p.L174= | Silent (SNP) | VAF 21/400 reads (5%) | called by muse, mutect2
- KIF25 | c.1074C>A p.I358= (on ENST00000354419 / NM_030615.2; = p.I306= on NM_005355.3) | Silent (SNP) | VAF 13/197 reads (7%) | called by muse, mutect2
- NLRP12 | c.1455C>A p.G485= | Silent (SNP) | VAF 68/442 reads (15%) | called by muse, mutect2, varscan2
- OR14C36 | c.804G>A p.Q268= | Silent (SNP) | VAF 18/354 reads (5%) | catalogued as COSV58603229; called by muse, mutect2
- PCLO | c.8472C>G p.L2824= | Silent (SNP) | VAF 14/272 reads (5%) | catalogued as COSV61655320; called by muse, mutect2
- RABGEF1 | c.855C>A p.I285= (on ENST00000439720 / NM_001287061.2; = p.I272= on NM_014504.3 and 29 other RefSeq transcripts) | Silent (SNP) | VAF 16/240 reads (7%) | called by muse, mutect2
- RANBP2 | c.6207C>G p.G2069= | Silent (SNP) | VAF 103/843 reads (12%) | called by muse, mutect2, varscan2
- RYR2 | c.12465C>T p.S4155= | Silent (SNP) | VAF 11/107 reads (10%) | called by muse, mutect2, varscan2
- SI | c.81A>G p.L27= | Silent (SNP) | VAF 13/125 reads (10%) | called by muse, mutect2, varscan2
- SLC12A3 | c.534G>A p.S178= | Silent (SNP) | VAF 28/531 reads (5%) | catalogued as rs140931462, COSV52638074; called by muse, mutect2
- TENT5D | c.375C>T p.I125= | Silent (SNP) | VAF 25/237 reads (11%) | catalogued as COSV57639564; called by muse, mutect2, varscan2
- TFPT | c.303C>T p.N101= | Silent (SNP) | VAF 21/243 reads (9%) | catalogued as rs762665827, COSV57838256; called by muse, mutect2
- TLE2 | c.1602G>A p.A534= | Silent (SNP) | VAF 12/132 reads (9%) | catalogued as rs770219759; called by muse, mutect2
- TTN | c.32643C>A p.P10881= (on ENST00000591111; = p.P9954= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/194 reads (4%) | called by muse, mutect2
- TUSC3 | c.513T>A p.I171= | Silent (SNP) | VAF 45/348 reads (13%) | called by muse, mutect2, varscan2
- ADARB2 | c.101-147686C>A | Intron (SNP) | VAF 19/126 reads (15%) | called by muse, mutect2, varscan2
- ANKMY1 | c.-9G>A | 5'UTR (SNP) | VAF 20/252 reads (8%) | called by muse, mutect2
- DPRX | c.-9G>C | 5'UTR (SNP) | VAF 12/170 reads (7%) | called by muse, mutect2
- EGFL7 | c.*5C>T | 3'UTR (SNP) | VAF 9/129 reads (7%) | called by muse, mutect2
- IGFN1 | c.1242-2263G>T | Intron (SNP) | VAF 127/559 reads (23%) | catalogued as rs1434695038; called by muse, mutect2, varscan2
- NAP1L4 | c.*91G>A | 3'UTR (SNP) | VAF 28/98 reads (29%) | called by muse, mutect2, varscan2
- OXCT1 | c.-6C>A | 5'UTR (SNP) | VAF 12/206 reads (6%) | catalogued as rs1201610821; called by muse, mutect2
- XIRP2 | c.*1499G>T | 3'UTR (SNP) | VAF 16/115 reads (14%) | catalogued as COSV99746367; called by muse, mutect2, varscan2
